Somatic mutation profile of tumor specimen TCGA-EE-A2MC-06A (aliquot TCGA-EE-A2MC-06A-12D-A197-08) from TCGA case TCGA-EE-A2MC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 74.7 years (27,298 days).
Specimen TCGA-EE-A2MC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d03e3cee-5c73-4756-beb2-0fea6f04558f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2MC-10A (Blood Derived Normal), aliquot TCGA-EE-A2MC-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d636944-83b9-4075-b94e-f683105e1f18

The open-access MAF lists 912 somatic variants for this specimen: 597 protein-altering or splice-affecting, 288 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 534, Silent 288, Nonsense Mutation 40, Splice Region 10, Intron 10, Splice Site 8, RNA 6, 3'UTR 4, 5'UTR 3, 5'Flank 2, 3'Flank 2, Translation Start Site 2.

Variants (750 of 912; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.4031C>T p.S1344L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV58615689; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 35/148 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.2528C>T p.S843F | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs763452733, COSV55293290; called by muse, mutect2, varscan2
- ABCA13 | c.13638C>T p.F4546= | Splice Region (SNP) | VAF 9/57 reads (16%) | catalogued as rs373145026, COSV68949876; called by muse, mutect2, varscan2
- AC097637.1 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs770001792, COSV59726750; called by muse, mutect2, varscan2
- AC126283.2 | c.1418G>A p.G473E | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1177188965, COSV67099098; called by muse, mutect2, varscan2
- ACVR1C | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54644212; called by muse, mutect2, varscan2
- ADA | c.679-1G>A p.X227_splice | Splice Site (SNP) | VAF 31/136 reads (23%) | catalogued as COSV63069042; called by muse, mutect2, varscan2
- ADAM18 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs267601916, COSV55844457; called by muse, mutect2, varscan2
- ADAM18 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs752996370, COSV55844420, COSV55851975; called by muse, mutect2, varscan2
- ADAMTS14 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs1418535072, COSV64603654; called by muse, mutect2, varscan2
- ADAMTS16 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs1357396242, COSV56981173; called by muse, mutect2, varscan2
- ADAMTS19 | c.2638C>T p.P880S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50761133; called by muse, mutect2, varscan2
- ADAP2 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as COSV58296410; called by muse, mutect2, varscan2
- ADGRG3 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV59650844; called by muse, mutect2, varscan2
- ADGRV1 | c.7644G>A p.M2548I | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV67988752; called by muse, varscan2
- ADGRV1 | c.7771G>A p.E2591K | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs757315634, COSV67978987; called by muse, varscan2
- ADGRV1 | c.10789G>A p.E3597K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.182); catalogued as rs866992177, COSV67988757; called by muse, mutect2, varscan2
- ADH1B | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 72/411 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.458); catalogued as COSV59297170; called by muse, mutect2, varscan2
- AFF2 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV53995494; called by muse, mutect2, varscan2
- AFF4 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as COSV54792285; called by muse, mutect2, varscan2
- AGL | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV54054514; called by muse, mutect2, varscan2
- AGO4 | c.1507A>G p.T503A | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV64617669; called by muse, mutect2, varscan2
- AGPAT4 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.11); catalogued as COSV57247439; called by muse, mutect2
- AHNAK2 | c.10304C>T p.S3435F | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV60920068; called by muse, mutect2, varscan2
- AKAP9 | c.5935C>T p.R1979C (on ENST00000359028; = p.R1947C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62337737; called by muse, mutect2, varscan2
- AKNA | c.3724C>T p.P1242S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as COSV56338090; called by muse, mutect2, varscan2
- ALDH1A2 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs963837318, COSV51083900; called by muse, mutect2, varscan2
- ALK | c.2903C>T p.P968L | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.636); catalogued as COSV66574972; called by muse, mutect2, varscan2
- ALMS1 | c.4166G>A p.S1389N | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs761560436, COSV52513471; called by muse, mutect2, varscan2
- ALOX15B | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.702); catalogued as COSV66479660; called by muse, mutect2, varscan2
- ALS2 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51887037, COSV51888811; called by muse, mutect2, varscan2
- ANK1 | c.4048G>A p.E1350K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV55885737; called by muse, mutect2, varscan2
- ANK3 | c.6551C>T p.P2184L | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV55042400; called by muse, mutect2, varscan2
- ANK3 | c.4370G>A p.R1457Q (on ENST00000280772 / NM_001320874.2; = p.R582Q on NM_001149.3) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.78); catalogued as rs758325260, COSV55065496; called by mutect2, varscan2
- ANK3 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55065523; called by muse, mutect2, varscan2
- ANO7 | c.674C>T p.P225L (on ENST00000274979; = p.P171L on NM_001370694.2) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV51473822, COSV99239088; called by muse, mutect2, varscan2
- ANO8 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.594); catalogued as COSV50184674; called by muse, mutect2, varscan2
- APOBEC2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758980965, COSV55142980; called by muse, mutect2, varscan2
- ARAP2 | c.4514G>A p.G1505E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs144848991; called by muse, mutect2, varscan2
- ARID2 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 15/76 reads (20%) | catalogued as COSV57607234; called by muse, mutect2, varscan2
- ARL4D | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV60721410; called by muse, mutect2, varscan2
- ARMC4 | c.2944G>A p.A982T | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.425); catalogued as rs146309511; called by muse, mutect2, varscan2
- ARSI | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60817826; called by muse, mutect2, varscan2
- ASH2L | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51700205; called by muse, mutect2
- ASNSD1 | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53623847; called by muse, varscan2
- ASXL3 | c.2783G>A p.G928E | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); catalogued as COSV52456596; called by muse, mutect2, varscan2
- ATMIN | c.1118A>G p.N373S | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV55146610; called by muse, mutect2, varscan2
- ATP13A1 | c.1528A>T p.K510* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV52287977; called by mutect2, varscan2
- ATP13A5 | c.2396G>A p.G799E | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs370197298, COSV60874479; called by muse, mutect2, varscan2
- ATP4A | c.2686G>A p.G896R | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV52869151; called by muse, mutect2, varscan2
- ATP6V1H | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs774963761, COSV62219017; called by mutect2, varscan2
- BACH2 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs1469024903, COSV57598244; called by muse, mutect2, varscan2
- BLK | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202149014, COSV52053529; called by muse, mutect2, varscan2
- BMPER | c.1320G>A p.W440* | Nonsense Mutation (SNP) | VAF 21/101 reads (21%) | catalogued as COSV51823431; called by muse, mutect2, varscan2
- BRINP1 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as COSV56301399; called by muse, mutect2, varscan2
- C12orf54 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs868088728, COSV58359933; called by muse, mutect2
- C12orf56 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs764750881, COSV61487157; called by muse, mutect2, varscan2
- C14orf39 | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1423145173, COSV58780220, COSV58783087; called by muse, mutect2, varscan2
- C1orf194 | c.131G>A p.W44* (on ENST00000369948 / NM_001245025.3; = p.W32* on NM_001122961.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 36/197 reads (18%) | catalogued as COSV64050018; called by muse, mutect2, varscan2
- C22orf31 | c.116A>G p.N39S | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV53310781; called by muse, mutect2
- C2orf42 | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV52451124; called by muse, mutect2, varscan2
- C3orf20 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as rs1414839912, COSV53786585; called by muse, mutect2, varscan2
- C7 | c.1328G>A p.W443* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100496482; called by muse, mutect2
- CACNA1E | c.5227G>A p.E1743K | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62385594; called by muse, mutect2, varscan2
- CACNA1I | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs750090343, COSV60812114; called by muse, mutect2, varscan2
- CACNA1I | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.33); catalogued as rs746228837, COSV60801784; called by muse, mutect2, varscan2
- CACNG3 | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50072296, COSV99135261; called by muse, mutect2, varscan2
- CACNG4 | c.946C>T p.H316Y | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV50925883; called by muse, mutect2, varscan2
- CALB1 | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV55368249; called by muse, varscan2
- CALCOCO1 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV50415858; called by muse, mutect2, varscan2
- CARD14 | c.1090-2A>C p.X364_splice | Splice Site (SNP) | VAF 7/59 reads (12%) | catalogued as COSV60124608; called by muse, mutect2, varscan2
- CC2D1A | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as COSV58784530; called by muse, mutect2
- CCAR2 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV99373873; called by muse, mutect2, varscan2
- CCDC116 | c.392G>C p.S131T | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV53038114; called by muse, mutect2, varscan2
- CCDC65 | c.932G>A p.R311K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as COSV56739784; called by muse, mutect2, varscan2
- CCNB3 | c.1553C>T p.S518L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as COSV52075584; called by muse, mutect2
- CD163 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63129466; called by muse, mutect2, varscan2
- CD96 | c.986G>A p.G329E (on ENST00000283285 / NM_198196.3; = p.G313E on NM_005816.5) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51916053, COSV51921385; called by muse, mutect2, varscan2
- CDC25B | c.344C>T p.S115F (on ENST00000245960 / NM_021873.3; = p.S101F on NM_004358.4) | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs973112376, COSV55657814; called by muse, mutect2, varscan2
- CDC34 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 73/329 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53117194; called by muse, mutect2, varscan2
- CDH18 | c.1985G>A p.G662E | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV56909731; called by muse, mutect2, varscan2
- CDH23 | c.3219C>T p.I1073= | Splice Region (SNP) | VAF 13/55 reads (24%) | catalogued as rs778002868, COSV54940824; called by muse, mutect2
- CDHR2 | c.3877G>A p.G1293R | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.476); catalogued as rs757484467, COSV56140996; called by muse, mutect2, varscan2
- CDON | c.362T>G p.F121C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54999507; called by muse, mutect2, varscan2
- CELSR2 | c.2659T>C p.Y887H | Missense Mutation (SNP) | VAF 122/524 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54774622; called by muse, mutect2, varscan2
- CEP128 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV53675945; called by muse, mutect2, varscan2
- CFAP100 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 64/317 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61503542; called by muse, mutect2, varscan2
- CFAP54 | c.4745C>T p.S1582F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1298363002, COSV61573001; called by muse, mutect2
- CFAP54 | c.6976G>A p.V2326I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as rs1177592640, COSV61573005; called by muse, mutect2, varscan2
- CFAP58 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as rs758121685, COSV63834810; called by mutect2, varscan2
- CFAP65 | c.3584G>A p.G1195E | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58562772; called by muse, mutect2, varscan2
- CFAP94 | c.1483G>A p.D495N (on ENST00000320267 / NM_001352064.2; = p.D501N on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57233758; called by muse, mutect2, varscan2
- CFHR5 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56823704; called by muse, mutect2, varscan2
- CHD9 | c.3802A>T p.T1268S | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54612267; called by muse, mutect2, varscan2
- CHMP7 | c.1203C>A p.N401K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV57533255; called by muse, mutect2, varscan2
- CKAP2 | c.1907C>T p.S636F (on ENST00000378037 / NM_001098525.2; = p.S635F on NM_018204.5) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.66); catalogued as COSV51625105; called by muse, mutect2, varscan2
- CLCNKA | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58891019, COSV58892408; called by muse, mutect2, varscan2
- CLDN4 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52896322; called by muse, mutect2, varscan2
- CLEC5A | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69396684; called by muse, mutect2, varscan2
- CLVS1 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV57977831; called by muse, mutect2, varscan2
- CNBD1 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1347003433, COSV72976331, COSV72976564; called by muse, mutect2, varscan2
- CNGA2 | c.375G>A p.K125= | Splice Region (SNP) | VAF 28/76 reads (37%) | catalogued as COSV61705163; called by muse, varscan2
- CNGB3 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs376711003, COSV60692258; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP2 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as COSV62208504; called by muse, mutect2, varscan2
- COA4 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV60156090; called by muse, mutect2, varscan2
- COL11A2 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs886100388, COSV59498686; called by muse, mutect2, varscan2
- COL12A1 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV59399427; called by muse, mutect2, varscan2
- COL24A1 | c.3739G>A p.E1247K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.183); catalogued as rs199669304, COSV65308657; called by muse, mutect2, varscan2
- COL2A1 | c.3614C>T p.P1205L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV61531903; called by muse, mutect2
- COL3A1 | c.3931C>T p.P1311S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV58591450; called by muse, mutect2, varscan2
- COL5A2 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs760216151, COSV66411176; called by mutect2, varscan2
- CPEB3 | c.1144A>G p.M382V | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs774076302, COSV56458803; called by muse, mutect2, varscan2
- CR1 | c.3683C>T p.P1228L | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65459639; called by muse, mutect2, varscan2
- CRB1 | c.2215C>T p.L739F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs771762730, COSV66331366; called by muse, mutect2, varscan2
- CREG2 | c.568A>G p.M190V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs780305968, COSV61317211; called by muse, mutect2, varscan2
- CRLF2 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.371); catalogued as rs752740413, COSV67493890; called by muse, mutect2, varscan2
- CRMP1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV61479573; called by muse, mutect2, varscan2
- CRYBG1 | c.3251C>T p.P1084L | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV64812937; called by muse, mutect2
- CSPP1 | c.3721G>A p.E1241K (on ENST00000676605; = p.E1200K on NM_024790.6) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.795); catalogued as rs201972175, COSV99139068; called by muse, mutect2
- CTNNA2 | c.219A>T p.E73D | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV63580127; called by muse, mutect2, varscan2
- CUL4A | c.1755G>T p.G585= (on ENST00000375440 / NM_001008895.4; = p.G485= on NM_003589.3) | Splice Region (SNP) | VAF 16/140 reads (11%) | catalogued as COSV100417092; called by muse, mutect2
- CUL4A | c.1757A>G p.K586R (on ENST00000375440 / NM_001008895.4; = p.K486R on NM_003589.3) | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV58373889; called by muse, mutect2
- CUL9 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV52730545; called by muse, mutect2, varscan2
- CUTC | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.948); catalogued as rs867119673, COSV65081953; called by muse, mutect2, varscan2
- CUZD1 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs556196978, COSV59027153; called by muse, mutect2, varscan2
- CYYR1 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763085488, COSV54834090; called by muse, mutect2, varscan2
- DACH1 | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV57507167, COSV57509798; called by muse, mutect2, varscan2
- DCC | c.4009C>T p.R1337* | Nonsense Mutation (SNP) | VAF 26/102 reads (25%) | catalogued as rs773315729, COSV71427767; called by muse, mutect2, varscan2
- DCDC1 | c.2947G>A p.E983K (on ENST00000597505 / NM_001367979.1; = p.E90K on NM_020869.3) | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV60308364; called by muse, mutect2, varscan2
- DCTN4 | c.537G>A p.S179= | Splice Region (SNP) | VAF 12/54 reads (22%) | catalogued as rs757861882, COSV69781746; called by muse, mutect2, varscan2
- DENND3 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52803785; called by muse, mutect2, varscan2
- DGKE | c.1498C>T p.R500* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as rs1342368899, COSV52349569; called by muse, mutect2, varscan2
- DHCR7 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM000370, COSV62795755; called by muse, mutect2, varscan2
- DISP3 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.066); catalogued as COSV53830548; called by muse, mutect2
- DLGAP3 | c.2375C>T p.P792L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV52395210; called by muse, mutect2, varscan2
- DMBT1 | c.3196G>A p.E1066K (on ENST00000338354 / NM_001377530.1; = p.E567K on NM_004406.3) | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs762373579, COSV57549215; called by muse, mutect2, varscan2
- DMBX1 | c.1088A>C p.N363T | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.755); catalogued as COSV63602245; called by muse, mutect2
- DMRT3 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as rs748535774, COSV51905930; called by muse, mutect2, varscan2
- DMRTC2 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV54187260; called by muse, mutect2, varscan2
- DMTF1 | c.89T>C p.I30T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as COSV58686517; called by muse, mutect2, varscan2
- DNAH5 | c.9720G>A p.M3240I | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99446270; called by muse, mutect2, varscan2
- DNAH9 | c.5890C>T p.P1964S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.394); catalogued as COSV52357883; called by muse, mutect2, varscan2
- DOCK2 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56968130; called by muse, mutect2, varscan2
- DOCK2 | c.4868C>T p.P1623L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV56968142; called by muse, mutect2, varscan2
- DOP1B | c.1858G>A p.G620S | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.419); catalogued as rs1157367666, COSV67696999; called by muse, mutect2, varscan2
- DSC2 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51866434; called by muse, varscan2
- DSC3 | c.938G>A p.R313K | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV64573744; called by muse, mutect2
- DSG3 | c.1495A>G p.K499E | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.029); catalogued as COSV99933878; called by muse, varscan2
- DSG3 | c.1496A>C p.K499T | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV99933879; called by muse, varscan2
- DZIP1L | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as COSV59521955; called by muse, mutect2, varscan2
- EBF2 | c.1688G>A p.G563E | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as rs776859966, COSV68776429; called by muse, mutect2, varscan2
- EIF4G3 | c.2293T>G p.L765V | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51686500, COSV99946162; called by muse, mutect2, varscan2
- ENOX1 | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54905467; called by muse, mutect2, varscan2
- EPHA3 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60713162; called by muse, mutect2, varscan2
- EPHA7 | c.2708C>T p.P903L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.138); catalogued as COSV65186038; called by muse, mutect2, varscan2
- EPO | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.247); catalogued as COSV53161254; called by muse, mutect2, varscan2
- EPX | c.670T>C p.F224L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.771); catalogued as COSV56597199; called by muse, mutect2
- ERBB4 | c.1984T>C p.F662L | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.98); catalogued as COSV53506982, COSV53548835; called by muse, mutect2, varscan2
- ERC2 | c.2562G>A p.M854I | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs937311613, COSV55616057; called by muse, mutect2, varscan2
- ERICH3 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs753898326, COSV58610748; called by muse, mutect2, varscan2
- EVC2 | c.2202C>G p.D734E | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60396308; called by muse, mutect2, varscan2
- EXOSC5 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs377456809, COSV55371023; called by muse, mutect2
- F13A1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs761188694, COSV53555015; called by muse, varscan2
- F2R | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV59929460; called by muse, mutect2, varscan2
- F2RL1 | c.1081T>A p.C361S | Missense Mutation (SNP) | VAF 97/535 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV56996022; called by muse, mutect2, varscan2
- F5 | c.4154C>T p.S1385F | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV100889075, COSV63125487; called by muse, mutect2, varscan2
- FABP1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV55557836, COSV55558503; called by muse, mutect2, varscan2
- FAM131A | c.902G>T p.C301F (on ENST00000310585; = p.C332F on NM_144635.5) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.693); catalogued as COSV99658309; called by muse, mutect2, varscan2
- FAM135A | c.4489G>C p.D1497H (on ENST00000370479 / NM_001351599.1; = p.D1284H on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52054018; called by muse, mutect2, varscan2
- FAM13C | c.1286G>A p.R429K | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53251116; called by muse, mutect2, varscan2
- FAM160A2 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs529633386, COSV56412499; called by muse, mutect2, varscan2
- FAM221B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65073698; called by muse, mutect2, varscan2
- FAM83C | c.1562G>A p.G521E | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.182); catalogued as COSV65583547; called by muse, mutect2, varscan2
- FAM83E | c.1345T>A p.F449I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV52377051; called by muse, mutect2, varscan2
- FANCB | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV60760652; called by muse, mutect2, varscan2
- FAT2 | c.12064G>A p.E4022K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV55823132; called by muse, mutect2
- FAT3 | c.3626C>T p.S1209L | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1232461746, COSV53110493; called by muse, mutect2, varscan2
- FBXO24 | c.41T>G p.V14G (on ENST00000241071 / NM_033506.3; = p.V52G on NM_012172.5) | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs776762431, COSV53827226; called by muse, mutect2, varscan2
- FCAR | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as COSV62029575; called by muse, mutect2, varscan2
- FGD6 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV59694463; called by muse, mutect2, varscan2
- FKBP8 | c.608C>T p.A203V (on ENST00000222308 / NM_001308373.2; = p.A204V on NM_012181.5) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.03); catalogued as COSV55892978; called by muse, mutect2
- FN1 | c.6676G>A p.E2226K (on ENST00000359671 / NM_001365524.2; = p.E2195K on NM_002026.4) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.5); catalogued as COSV60556594; called by muse, mutect2, varscan2
- FRG2B | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs570995159, COSV71043016; called by muse, mutect2, varscan2
- FRMPD1 | c.2455G>A p.G819R | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV66700983; called by muse, mutect2, varscan2
- FSTL5 | c.1282C>T p.L428F | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60205353; called by muse, mutect2, varscan2
- GABBR2 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs978945843, COSV52309784; called by muse, mutect2, varscan2
- GABBR2 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.142); catalogued as COSV52309793; called by muse, mutect2, varscan2
- GABRE | c.769A>T p.I257F | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV64820167; called by muse, mutect2
- GADD45GIP1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV57536659; called by muse, mutect2, varscan2
- GART | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.882); catalogued as rs1008057042, COSV63113997; called by muse, mutect2
- GATA4 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs377673676, CM1010267; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GIMAP7 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57959691; called by muse, mutect2, varscan2
- GJA4 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.041); catalogued as rs1214797728, COSV60725624; called by muse, mutect2, varscan2
- GKAP1 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as rs779065718, COSV64489260; called by muse, mutect2, varscan2
- GKN1 | c.68A>G p.N23S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.194); catalogued as rs565532872, COSV65006612; called by muse, mutect2, varscan2
- GLDN | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs750373261, COSV100118139, COSV59089020; called by muse, mutect2, varscan2
- GLI3 | c.4444C>T p.P1482S | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV67887230; called by muse, mutect2, varscan2
- GNRH2 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs1199020729, COSV55661664; called by muse, mutect2, varscan2
- GOLM1 | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as rs370934795; called by muse, mutect2, varscan2
- GPR39 | c.1106A>G p.N369S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV61416902; called by muse, mutect2, varscan2
- GREB1 | c.3096G>A p.M1032I | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.64); catalogued as COSV52189480; called by muse, mutect2, varscan2
- GRM3 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1320241384, COSV64474551; called by muse, mutect2, varscan2
- GRM3 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV64469402; called by muse, varscan2
- GRM7 | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.658); catalogued as rs780911660, COSV63150933, COSV63155397; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV63100510; called by muse, mutect2, varscan2
- GUCA1B | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs771976584, COSV50004489, COSV50005311; called by muse, mutect2, varscan2
- H2AC1 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs771731847, COSV51237668; called by mutect2, varscan2
- H4-16 | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as COSV63762238; called by muse, mutect2, varscan2
- HAP1 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV57879022; called by muse, mutect2, varscan2
- HDAC8 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV65275239; called by muse, mutect2
- HDAC9 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752484524, COSV67770493; called by muse, mutect2, varscan2
- HEATR5B | c.4502C>T p.S1501F | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV51854736; called by muse, mutect2, varscan2
- HECTD4 | c.12193C>T p.H4065Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV66394403; called by muse, mutect2
- HERC2 | c.3260C>T p.S1087F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99871659; called by muse, mutect2, varscan2
- HHATL | c.1178A>C p.N393T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55135406; called by muse, mutect2, varscan2
- HHLA2 | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.052); catalogued as COSV63318190; called by muse, mutect2, varscan2
- HMGCS2 | c.1422G>A p.V474= | Splice Region (SNP) | VAF 41/206 reads (20%) | catalogued as COSV65567731; called by muse, mutect2, varscan2
- HOMER2 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58486876; called by muse, varscan2
- HYDIN | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.54); catalogued as COSV55478731; called by muse, mutect2, varscan2
- IDO1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV53714154; called by muse, mutect2, varscan2
- IGF2R | c.7136C>T p.P2379L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV63630331; called by muse, mutect2, varscan2
- IGSF1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.205); catalogued as COSV63838371; called by muse, mutect2, varscan2
- IL17RE | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV55969177; called by muse, mutect2, varscan2
- IL3RA | c.278G>A p.W93* | Nonsense Mutation (SNP) | VAF 62/297 reads (21%) | catalogued as COSV58432015; called by muse, mutect2, varscan2
- ILDR1 | c.794C>T p.S265F (on ENST00000344209 / NM_001199799.2; = p.S221F on NM_175924.4) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.451); catalogued as rs146027039; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INPPL1 | c.2594A>T p.N865I | Missense Mutation (SNP) | VAF 39/280 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.896); catalogued as COSV53356837; called by muse, mutect2, varscan2
- INSRR | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.239); catalogued as COSV100947253; called by muse, mutect2, varscan2
- IQUB | c.2102G>A p.W701* | Nonsense Mutation (SNP) | VAF 21/149 reads (14%) | catalogued as COSV61240295; called by muse, mutect2, varscan2
- ITGA3 | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.135); catalogued as COSV50318747; called by muse, mutect2, varscan2
- ITGA4 | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52001392; called by muse, mutect2, varscan2
- ITGA7 | c.1774C>T p.R592C (on ENST00000555728; = p.R548C on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs146411608, COSV57697061, COSV99144133; called by muse, mutect2, varscan2
- ITGB4 | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs763137689, COSV52328686; called by muse, mutect2, varscan2
- ITIH2 | c.2518G>A p.D840N | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV64433950; called by muse, mutect2, varscan2
- ITM2B | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.366); catalogued as COSV101052294; called by muse, mutect2, varscan2
- KCNJ10 | c.175T>C p.F59L | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.354); catalogued as COSV63634148; called by muse, mutect2, varscan2
- KCNN3 | c.1930G>A p.V644M (on ENST00000618040 / NM_001204087.1; = p.V629M on NM_002249.6) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs1557937420, COSV55220194; called by muse, mutect2, varscan2
- KIF18B | c.1268G>A p.G423E (on ENST00000593135 / NM_001265577.2; = p.G435E on NM_001264573.2) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs908218464, COSV59274241; called by muse, mutect2, varscan2
- KIF1B | c.1325C>T p.S442F (on ENST00000377086 / NM_001365952.1; = p.S396F on NM_015074.3) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs908437722, COSV55810986; called by muse, mutect2, varscan2
- KIF20B | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53310165; called by muse, mutect2, varscan2
- KIR3DL2 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.999); catalogued as COSV54393432; called by muse, mutect2, varscan2
- KIR3DL2 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99552044; called by muse, mutect2, varscan2
- KITLG | c.704T>C p.L235S | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV57202595; called by muse, mutect2, varscan2
- KLHL1 | c.1811C>T p.S604L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV100917010, COSV64775421; called by muse, mutect2, varscan2
- KLHL13 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53249609, COSV53253763; called by muse, mutect2, varscan2
- KLHL17 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1557632374, COSV58532473; called by muse, mutect2
- KLHL32 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV65111804; called by muse, mutect2, varscan2
- KMT2B | c.7349G>A p.R2450Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs1296301139, COSV55820920; called by muse, mutect2
- KRT10 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.27); catalogued as COSV54090316; called by muse, mutect2
- KRT16 | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 42/162 reads (26%) | catalogued as rs750113720, COSV56968666; called by muse, mutect2, varscan2
- KRT34 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760449691, COSV67450097; called by muse, mutect2, varscan2
- KRT35 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55843688; called by muse, mutect2, varscan2
- KRT39 | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 35/269 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs1272614602, COSV62917558; called by muse, mutect2, varscan2
- KRT9 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55853426, COSV55853948; called by muse, mutect2, varscan2
- LAMB3 | c.2467C>T p.P823S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV61917961; called by muse, mutect2, varscan2
- LBHD1 | c.502A>T p.T168S (on ENST00000431002 / NM_001367940.1; = p.T142S on NM_024099.3) | Missense Mutation (SNP) | VAF 122/390 reads (31%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as COSV63473183; called by muse, mutect2, varscan2
- LCTL | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs113055189, COSV58421486; called by muse, mutect2
- LDB2 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as rs747666812, COSV58766051; called by muse, mutect2, varscan2
- LGALS2 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50757118; called by muse, mutect2, varscan2
- LILRA5 | c.126G>A p.G42= | Splice Region (SNP) | VAF 10/67 reads (15%) | catalogued as COSV56643609; called by muse, mutect2, varscan2
- LILRB1 | c.1415C>A p.T472K (on ENST00000427581; = p.T436K on NM_006669.6) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV100207033; called by muse, mutect2
- LINGO2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.803); catalogued as rs1329891686, COSV58061180; called by muse, mutect2, varscan2
- LIPC | c.1295C>G p.T432R | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.115); catalogued as COSV54424126; called by muse, mutect2, varscan2
- LIPH | c.1055G>A p.R352K | Missense Mutation (SNP) | VAF 112/560 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV56182891, COSV56184664; called by muse, mutect2, varscan2
- LRP2 | c.12955C>T p.R4319* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as rs868444553, COSV55549994; called by muse, mutect2, varscan2
- LRP2 | c.8509C>T p.P2837S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.39); catalogued as rs745718781, COSV55560078; called by muse, mutect2, varscan2
- LRRC52 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV54232626; called by muse, mutect2, varscan2
- LRRIQ3 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs202037480, COSV63041614, COSV99063517; called by muse, mutect2, varscan2
- LVRN | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as COSV63497610; called by muse, mutect2, varscan2
- LY6K | c.420G>T p.M140I | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV52832691, COSV99456199; called by muse, varscan2
- LY6K | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99456202; called by muse, mutect2, varscan2
- MADD | c.4859C>T p.S1620F | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs267602903, COSV57028850; called by muse, mutect2, varscan2
- MAP10 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 40/204 reads (20%) | PolyPhen benign (0); catalogued as COSV69364031; called by muse, mutect2, varscan2
- MAP2K4 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV62258563; called by muse, mutect2, varscan2
- MCM3AP | c.4574C>T p.S1525L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV52441611; called by muse, mutect2, varscan2
- MCTP2 | c.2568G>A p.K856= | Splice Region (SNP) | VAF 10/71 reads (14%) | catalogued as rs758689438, COSV63294803; called by muse, mutect2
- MECOM | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs758678191, COSV72110712; called by muse, mutect2, varscan2
- MEIS2 | c.100C>T p.P34S (on ENST00000561208 / NM_170675.5; = p.P21S on NM_002399.3) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as rs1289568511, COSV54939040; called by muse, mutect2, varscan2
- MGAM | c.4075C>T p.P1359S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs866544940, COSV72074972; called by muse, mutect2, varscan2
- MICAL2 | c.2815C>T p.H939Y | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56322098; called by muse, mutect2
- MIOX | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV53313606; called by muse, mutect2, varscan2
- MLXIP | c.2126C>T p.S709F | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as rs760600926, COSV59833869, COSV59836400; called by muse, mutect2, varscan2
- MMP13 | c.511+1G>A p.X171_splice | Splice Site (SNP) | VAF 5/15 reads (33%) | catalogued as COSV52824517; called by muse, mutect2
- MMP16 | c.1599T>G p.D533E | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV54173166; called by muse, mutect2, varscan2
- MPDZ | c.6181A>G p.K2061E (on ENST00000319217 / NM_001330637.2; = p.K2032E on NM_003829.5) | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1026062304, COSV59919783; called by muse, mutect2, varscan2
- MRAP2 | c.270T>G p.F90L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.136); catalogued as COSV57633071; called by muse, mutect2, varscan2
- MRO | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV56496943; called by muse, mutect2, varscan2
- MROH2B | c.2500C>T p.R834W | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368507319; called by muse, mutect2, varscan2
- MROH7 | c.2111G>A p.G704E | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV59874029; called by muse, mutect2, varscan2
- MRPL10 | c.542T>C p.I181T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs770760016, COSV50110641; called by muse, mutect2, varscan2
- MRS2 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.545); catalogued as COSV51234726; called by muse, mutect2, varscan2
- MUC13 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV60700177; called by muse, mutect2, varscan2
- MUC16 | c.41128C>T p.H13710Y | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.824); catalogued as rs763597726, COSV101109691; called by muse, mutect2, varscan2
- MUC16 | c.38984G>A p.G12995E | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.455); catalogued as rs796151917, COSV67452671; called by muse, mutect2
- MUC16 | c.29164G>A p.E9722K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as COSV67473438; called by muse, mutect2, varscan2
- MUC16 | c.27133G>A p.G9045R | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV67476154; called by muse, mutect2
- MUC16 | c.9394G>A p.E3132K | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as COSV67456669, COSV67476163; called by muse, mutect2, varscan2
- MUCL3 | c.1540C>T p.P514S (on ENST00000304311; = p.P1390S on NM_080870.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.916); catalogued as COSV58517878; called by muse, mutect2, varscan2
- MXRA5 | c.7994G>A p.G2665E | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54240270; called by muse, mutect2, varscan2
- MYBPC1 | c.1073G>C p.R358T (on ENST00000550270 / NM_206820.2; = p.R383T on NM_002465.4) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as rs747972508, COSV62254357; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH14 | c.5239G>A p.E1747K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1479041065, COSV51822652; called by muse, mutect2, varscan2
- MYH2 | c.4386G>A p.W1462* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV55431924; called by muse, mutect2, varscan2
- MYH2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); catalogued as COSV55440934, COSV55441376; called by muse, mutect2, varscan2
- MYH7 | c.3847G>A p.E1283K | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62520880; called by muse, mutect2, varscan2
- MYL1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 103/271 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV61681269; called by muse, mutect2, varscan2
- MYO3A | c.4607T>A p.L1536* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV56336914; called by mutect2, varscan2
- MYO5B | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53222733; called by muse, mutect2, varscan2
- MYT1 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.76); catalogued as COSV60508481; called by muse, mutect2, varscan2
- NAALADL1 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV60524636; called by muse, mutect2, varscan2
- NAP1L2 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV65172670; called by muse, mutect2, varscan2
- NBEA | c.6701G>A p.R2234Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV59760527; called by muse, mutect2, varscan2
- NDEL1 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs759251803, COSV55328088, COSV55328524; called by muse, mutect2, varscan2
- NETO2 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV57453718; called by muse, mutect2, varscan2
- NEXMIF | c.4501G>A p.V1501I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.011); catalogued as COSV50045047; called by muse, mutect2
- NKX2-1 | c.87G>A p.M29I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.204); catalogued as COSV61389270; called by muse, mutect2
- NLGN2 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57209361; called by muse, mutect2, varscan2
- NLRC5 | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV52657935; called by muse, mutect2, varscan2
- NLRP2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs1165462336, COSV54756823; called by muse, mutect2, varscan2
- NLRP7 | c.1856A>C p.K619T | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV60176705; called by muse, mutect2
- NLRP7 | c.1571G>A p.G524D | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60176711; called by muse, mutect2, varscan2
- NME8 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.93); catalogued as rs372513137; called by muse, varscan2
- NOVA1 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57480603; called by muse, mutect2, varscan2
- NPC1L1 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56926736; called by muse, mutect2, varscan2
- NPNT | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV59751451, COSV59754943; called by muse, mutect2, varscan2
- NPTX2 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1031855244, COSV55717193; called by muse, mutect2, varscan2
- NRXN3 | c.2221G>A p.G741R (on ENST00000335750 / NM_001330195.2; = p.G368R on NM_004796.6) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59810961; called by muse, mutect2
- NUGGC | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.476); catalogued as COSV100429046; called by muse, mutect2, varscan2
- NUGGC | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV58432905; called by muse, mutect2, varscan2
- NWD1 | c.3133G>A p.E1045K | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.307); catalogued as rs867664250, COSV60345060; called by muse, mutect2, varscan2
- OAZ3 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV58618569; called by muse, mutect2, varscan2
- OBI1 | c.854G>A p.S285N | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV56146167; called by muse, mutect2, varscan2
- OR10J3 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59954348; called by muse, mutect2, varscan2
- OR13C9 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs150686997; called by muse, mutect2, varscan2
- OR1S2 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as COSV56919698, COSV56921494; called by muse, mutect2, varscan2
- OR2G3 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs1028980569, COSV60682224; called by muse, mutect2, varscan2
- OR4C13 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV73648600; called by muse, mutect2
- OR4D1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1180788220, COSV52125465; called by muse, mutect2, varscan2
- OR51D1 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62914364; called by muse, mutect2, varscan2
- OR52A1 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs199986389; called by muse, mutect2, varscan2
- OR52A1 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61092733; called by muse, mutect2, varscan2
- OR52E2 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV58612915; called by muse, mutect2, varscan2
- OR52N4 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs776548473, COSV57890322; called by muse, mutect2, varscan2
- OR5A1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs200946342, COSV57377145; called by muse, mutect2
- OR5M10 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs776935495, COSV73242357; called by muse, mutect2, varscan2
- OR6C65 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.209); catalogued as rs146463326; called by muse, mutect2, varscan2
- OR8J1 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs757798830, COSV100275271, COSV57318936; called by muse, mutect2, varscan2
- OR8K1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs765355907, COSV54402453; called by muse, mutect2
- OR8K3 | c.715A>T p.T239S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV57132028; called by muse, mutect2, varscan2
- OR9A4 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV71885187; called by muse, mutect2, varscan2
- OR9G4 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV57249037; called by muse, mutect2, varscan2
- OTOA | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.022); catalogued as COSV53757596; called by muse, mutect2, varscan2
- OXGR1 | c.385A>C p.I129L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV53657853; called by muse, mutect2, varscan2
- PAFAH2 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65339738; called by muse, mutect2, varscan2
- PAK5 | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62030955; called by muse, mutect2, varscan2
- PAK5 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 47/253 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs773981325, COSV62025752; called by muse, mutect2, varscan2
- PAMR1 | c.1081C>T p.P361S (on ENST00000619888 / NM_001001991.3; = p.P378S on NM_015430.4) | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1439382529, COSV53513782; called by muse, mutect2, varscan2
- PAPPA | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60286632; called by muse, mutect2
- PARD3 | c.3088C>T p.R1030* | Nonsense Mutation (SNP) | VAF 13/97 reads (13%) | catalogued as rs201444228, COSV61048844; called by muse, mutect2
- PCDH11X | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967297768, COSV53455530; called by muse, mutect2, varscan2
- PCDH15 | c.3673A>G p.T1225A | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs61731381; called by muse, mutect2, varscan2
- PCDH7 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.901); catalogued as COSV100687983, COSV62340511; called by muse, mutect2, varscan2
- PCDHA5 | c.2299G>A p.D767N | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100972187, COSV65351171; called by muse, mutect2, varscan2
- PCDHA6 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.262); catalogued as COSV65351331; called by muse, mutect2, varscan2
- PCDHA8 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV100970310, COSV100970528; called by muse, mutect2, varscan2
- PCDHA8 | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.04); catalogued as COSV65328335; called by muse, mutect2, varscan2
- PCDHA9 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as COSV65323835; called by muse, mutect2
- PCDHB12 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53398131; called by muse, mutect2, varscan2
- PCDHB7 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.03); catalogued as rs146757937; called by muse, mutect2, varscan2
- PCDHB7 | c.773G>A p.G258D | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.433); catalogued as rs1214898221, COSV50783820; called by muse, mutect2, varscan2
- PCDHGA5 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.728); catalogued as rs1266306756, COSV53976166; called by muse, mutect2, varscan2
- PCED1B | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1011182869, COSV71395290; called by muse, mutect2, varscan2
- PCLO | c.4670G>A p.R1557Q | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1424768942, COSV61616342, COSV61629128; called by muse, mutect2, varscan2
- PCM1 | c.3854A>G p.Q1285R | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.426); catalogued as rs775496658, COSV59587507; called by muse, mutect2
- PDE1C | c.389T>C p.I130T | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58518331; called by muse, mutect2, varscan2
- PDE6A | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.61); catalogued as COSV54928887; called by muse, mutect2, varscan2
- PDE7B | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs868388213, COSV57497954; called by muse, mutect2, varscan2
- PDZRN3 | c.1350T>G p.S450R | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55205442; called by muse, mutect2, varscan2
- PEG3 | c.3490G>A p.E1164K | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV55626130, COSV99688217; called by muse, mutect2, varscan2
- PENK | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs573652413, COSV59240213, COSV59242061; called by muse, mutect2, varscan2
- PER2 | c.2464C>T p.P822S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as COSV54524967; called by muse, mutect2
- PHTF2 | c.838C>T p.L280F (on ENST00000248550 / NM_001366089.1; = p.L242F on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.142); catalogued as COSV50331247; called by muse, mutect2, varscan2
- PIGK | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.225); catalogued as rs1483411687, COSV63062601; called by muse, mutect2, varscan2
- PLA2G3 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV53207942; called by muse, mutect2
- PLAAT4 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 94/314 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV55373601; called by muse, mutect2, varscan2
- PLEKHM3 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1270053777, COSV70136385; called by muse, mutect2, varscan2
- PLXNA1 | c.5188C>T p.Q1730* | Nonsense Mutation (SNP) | VAF 14/114 reads (12%) | catalogued as COSV52528560; called by muse, mutect2, varscan2
- PLXNA4 | c.5407G>A p.D1803N | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58138356; called by muse, mutect2, varscan2
- PNMA2 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs368364116; called by muse, mutect2
- POGZ | c.3112C>T p.Q1038* | Nonsense Mutation (SNP) | VAF 18/130 reads (14%) | catalogued as COSV51852135; called by muse, mutect2, varscan2
- POLD1 | c.676C>T p.L226F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV70955784; called by muse, mutect2, varscan2
- POPDC3 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99633479; called by muse, mutect2, varscan2
- POSTN | c.1696C>T p.H566Y | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65713509; called by muse, mutect2, varscan2
- PPARG | c.179T>G p.F60C (on ENST00000287820 / NM_015869.5; = p.F30C on NM_005037.7) | Missense Mutation (SNP) | VAF 120/634 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV55143484; called by muse, mutect2, varscan2
- PPP2R5B | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs374703944; called by muse, mutect2, varscan2
- PPP2R5C | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV58273041; called by muse, mutect2, varscan2
- PRAMEF2 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.77); catalogued as COSV53576835; called by muse, mutect2, varscan2
- PRR23B | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.242); catalogued as rs1379403110, COSV100271968, COSV100272091; called by muse, mutect2, varscan2
- PRRC2C | c.6890C>T p.S2297L (on ENST00000367742; = p.S2295L on NM_015172.4) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV58902730; called by muse, mutect2, varscan2
- PSG1 | c.962G>A p.S321N | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1306524414, COSV99739013; called by muse, mutect2, varscan2
- PUM2 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57582744; called by muse, mutect2, varscan2
- PWWP2A | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV61046967; called by muse, mutect2, varscan2
- QSER1 | c.494C>T p.A165V (on ENST00000399302; = p.A294V on NM_001076786.3) | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.035); catalogued as COSV67901057; called by muse, mutect2, varscan2
- RAI1 | c.2392C>T p.P798S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs148947371; called by muse, mutect2, varscan2
- RBFOX1 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189994954, COSV60951723, COSV60957860; ClinVar: uncertain significance; called by muse, mutect2
- RBP3 | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs781847641; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REPS1 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57811887; called by muse, mutect2, varscan2
- RFX6 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as rs1177381547, COSV60586589; called by muse, mutect2, varscan2
- RIMBP2 | c.1130C>T p.S377L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55476739; called by muse, mutect2, varscan2
- RIMS1 | c.4790G>A p.R1597Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1447666261, COSV53442622; called by muse, mutect2, varscan2
- RNF17 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.24); catalogued as COSV55043775; called by muse, mutect2
- RNF216 | c.2020A>T p.K674* (on ENST00000425013 / NM_207116.3; = p.K731* on NM_207111.4) | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV66291358; called by muse, mutect2, varscan2
- RNF4 | c.423G>A p.E141= | Splice Region (SNP) | VAF 50/236 reads (21%) | catalogued as COSV58641728, COSV58642976; called by muse, mutect2, varscan2
- RNPEP | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55242062; called by muse, mutect2
- RORB | c.487T>G p.S163A (on ENST00000396204 / NM_001365023.1; = p.S152A on NM_006914.4) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65337362; called by muse, mutect2, varscan2
- RORB | c.727G>A p.E243K (on ENST00000396204 / NM_001365023.1; = p.E232K on NM_006914.4) | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs1196575322, COSV65337367; called by muse, mutect2, varscan2
- RP1 | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs866463020, COSV55120028; called by muse, mutect2, varscan2
- RP1L1 | c.3496G>A p.D1166N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs760568274, COSV66756957; called by muse, mutect2, varscan2
- RPS13 | c.209A>C p.K70T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs1481985886, COSV99930504; called by muse, mutect2, varscan2
- RTTN | c.6596-7C>T | Splice Region (SNP) | VAF 9/52 reads (17%) | catalogued as rs752615550, COSV55347505; called by muse, mutect2, varscan2
- RUNDC3B | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV55955052; called by muse, mutect2, varscan2
- RUNX1T1 | c.490G>A p.E164K (on ENST00000265814 / NM_001198628.1; = p.E137K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV56152345, COSV56153261; called by muse, mutect2, varscan2
- RYR1 | c.925A>G p.K309E | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.966); catalogued as COSV62101761; called by muse, mutect2, varscan2
- RYR1 | c.6376C>T p.R2126W | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1265086155, COSV62101765; ClinVar: uncertain significance; called by muse, mutect2
- SAG | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68591414; called by muse, varscan2
- SALL1 | c.3652C>T p.Q1218* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV51759870; called by muse, mutect2, varscan2
- SALL1 | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51759877; called by muse, mutect2, varscan2
- SAMD9 | c.4039C>T p.L1347F | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs749496405, COSV66076326; called by muse, mutect2, varscan2
- SAP130 | c.2836T>C p.W946R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52099188; called by muse, mutect2, varscan2
- SATB2 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as rs780366664, COSV53487169; called by muse, mutect2, varscan2
- SCAF1 | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1413625348, COSV62183843; called by muse, mutect2
- SCARA3 | c.605T>G p.L202R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV57270637; called by muse, mutect2, varscan2
- SCARB1 | c.604A>G p.K202E | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.912); catalogued as rs141478587; called by muse, mutect2, varscan2
- SCG5 | c.133C>T p.H45Y | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.489); catalogued as COSV55707094; called by muse, mutect2, varscan2
- SCN1A | c.986G>A p.G329D | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs779184118, COSV57675605; called by muse, mutect2, varscan2
- SCN9A | c.4924C>T p.P1642S (on ENST00000303354; = p.P1631S on NM_002977.3) | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57614528; called by muse, mutect2, varscan2
- SELPLG | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs779200540, COSV57313494; called by muse, mutect2, varscan2
- SEMA3D | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 9/41 reads (22%) | catalogued as rs774391242, COSV52397199; called by muse, mutect2, varscan2
- SEMA4G | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779530961, COSV52969480, COSV52972608; called by mutect2, varscan2
- SEPTIN11 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as COSV53583128; called by muse, mutect2, varscan2
- SERPINA3 | c.947T>A p.F316Y | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67586495; called by muse, mutect2, varscan2
- SERPINB4 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV61985261; called by muse, mutect2, varscan2
- SERPINB7 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as rs527461202, COSV60533312, COSV60534645; called by muse, varscan2
- SEZ6 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV57982044; called by muse, mutect2, varscan2
- SGCZ | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101170437, COSV66023119; called by muse, mutect2, varscan2
- SGMS1 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV62371122; called by muse, mutect2, varscan2
- SHROOM3 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768503568, COSV56027817; called by muse, mutect2, varscan2
- SIGLEC5 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.513); catalogued as COSV55779097; called by muse, mutect2, varscan2
- SIGLEC8 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV58472035, COSV58474761; called by muse, mutect2, varscan2
- SIK3 | c.2293C>T p.Q765* (on ENST00000445177 / NM_001366686.2; = p.Q723* on NM_025164.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 40/279 reads (14%) | catalogued as COSV52617687; called by muse, mutect2, varscan2
- SIPA1L1 | c.4487C>T p.S1496F | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs867267891, COSV62170946; called by muse, mutect2, varscan2
- SKIV2L | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 54/473 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs376420612; called by muse, mutect2, varscan2
- SLC16A9 | c.1283T>C p.L428S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV68099448; called by muse, mutect2, varscan2
- SLC22A16 | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs761730512, COSV57931336; called by muse, mutect2, varscan2
- SLC22A25 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV60597014; called by muse, mutect2, varscan2
- SLC22A8 | c.1586G>A p.R529K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60325174; called by muse, mutect2, varscan2
- SLC26A4 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs868258887, COSV55914806, COSV55916478; called by muse, mutect2, varscan2
- SLC35F3 | c.908G>A p.G303E (on ENST00000366617 / NM_001300845.1; = p.G372E on NM_173508.4) | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV64019829; called by muse, mutect2
- SLC52A1 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54693204; called by muse, mutect2, varscan2
- SLC8A3 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs760107999, COSV63520262, COSV63523314, COSV63527549; called by muse, varscan2
- SLC9A9 | c.1430G>A p.G477E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57233494; called by muse, mutect2, varscan2
- SLC9C2 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs867737971, COSV62945191; called by muse, mutect2, varscan2
- SLCO1B1 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57007455; called by muse, mutect2, varscan2
- SLCO1B1 | c.761G>A p.W254* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | catalogued as COSV57013136; called by muse, mutect2, varscan2
- SLIT2 | c.4370G>A p.R1457K | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.108); catalogued as COSV56578946; called by muse, mutect2, varscan2
- SLITRK6 | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV68390614; called by muse, mutect2, varscan2
- SNAP25 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.367); catalogued as rs866969321, COSV54770798, COSV54771307; called by muse, mutect2, varscan2
- SPARCL1 | c.68T>A p.L23* | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | catalogued as COSV99215355; called by muse, mutect2, varscan2
- SPARCL1 | c.67T>G p.L23V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV99215358; called by muse, mutect2
- SPATA31E1 | c.3077G>A p.W1026* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV57793003; called by muse, mutect2, varscan2
- SPHKAP | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV60869360; called by muse, mutect2, varscan2
- SPOCD1 | c.3347G>A p.G1116D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV57097463; called by muse, mutect2
- SPOCK2 | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV58037114; called by muse, mutect2, varscan2
- SPP1 | c.651G>A p.W217* (on ENST00000395080 / NM_001040058.2; = p.W203* on NM_000582.2) | Nonsense Mutation (SNP) | VAF 31/127 reads (24%) | catalogued as rs375890642; called by muse, mutect2, varscan2
- SPTB | c.1956G>A p.W652* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as COSV67632968; called by muse, mutect2, varscan2
- SPTBN5 | c.9278G>A p.R3093K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.098); catalogued as COSV58023392; called by muse, mutect2, varscan2
- SRGAP1 | c.2566C>T p.P856S | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs748723181, COSV61893832; called by muse, mutect2, varscan2
- ST18 | c.2683C>T p.L895F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV52499149; called by muse, mutect2
- ST18 | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52489024; called by muse, mutect2, varscan2
- ST18 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV52489924; called by muse, mutect2, varscan2
- STARD4 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs369793461; called by mutect2, varscan2
- STRIP2 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as rs762567887, COSV50803968; called by muse, mutect2, varscan2
- STXBP5L | c.2138A>G p.N713S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.956); catalogued as COSV56520258; called by muse, mutect2, varscan2
- SYCE1 | c.743G>A p.R248K (on ENST00000343131 / NM_001143764.3; = p.R212K on NM_130784.3) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201035428, COSV100385745; called by muse, mutect2, varscan2
- SYNE1 | c.20977G>T p.A6993S (on ENST00000367255 / NM_182961.4; = p.A6922S on NM_033071.3) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55022231; called by muse, mutect2, varscan2
- SYT10 | c.1500+1G>T p.X500_splice | Splice Site (SNP) | VAF 21/94 reads (22%) | catalogued as COSV57342081; called by muse, mutect2, varscan2
- SYT3 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.167); catalogued as rs373338775; called by muse, varscan2
- TAF1L | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1315052396, COSV54264087; called by muse, mutect2, varscan2
- TBC1D9 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1478426991, COSV71307567; called by muse, mutect2
- TBC1D9 | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 35/191 reads (18%) | catalogued as rs916253445, COSV71306874; called by muse, mutect2, varscan2
- TBL1Y | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV60733339; called by muse, mutect2, varscan2
- TBX22 | c.998C>G p.S333C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64786710; called by muse, mutect2, varscan2
- TCHHL1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64285611, COSV64286129; called by muse, mutect2, varscan2
- TCN1 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57253717; called by muse, mutect2, varscan2
- TCP11L2 | c.1498C>T p.R500* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as rs199918617, COSV54429570; called by muse, mutect2, varscan2
- TENM1 | c.2828C>T p.P943L | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64435716; called by muse, mutect2, varscan2
- TENM1 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.4); catalogued as rs1246255736, COSV64435726; called by muse, mutect2, varscan2
- TENM3 | c.2802T>G p.N934K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV69312380; called by muse, mutect2, varscan2
- TENM3 | c.3505G>A p.G1169S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV69312386; called by muse, mutect2, varscan2
- TEX15 | c.263C>T p.S88L (on ENST00000256246; = p.S471L on NM_001350162.2) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.308); catalogued as rs146070106, COSV56345259; called by mutect2, varscan2
- TGM4 | c.979C>T p.H327Y | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56094778; called by muse, mutect2, varscan2
- THSD7B | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.272); catalogued as COSV55651433; called by muse, mutect2, varscan2
- TKTL2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV54919548; called by muse, mutect2
- TLE2 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs746239008, COSV53581022; called by muse, mutect2, varscan2
- TLL1 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV50297731; called by muse, mutect2, varscan2
- TLR4 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV62923307; called by muse, mutect2, varscan2
- TLR4 | c.673G>A p.E225K (on ENST00000355622 / NM_138554.5; = p.E185K on NM_003266.4) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV62922585, COSV62922718; called by muse, mutect2, varscan2
- TLR7 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.787); catalogued as rs868177091, COSV66124215; called by muse, mutect2, varscan2
- TMEM132A | c.2500G>A p.E834K (on ENST00000453848 / NM_178031.3; = p.E835K on NM_017870.4) | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.84); catalogued as rs1329660095, COSV50010215; called by muse, mutect2, varscan2
- TMEM174 | c.626+1G>A p.X209_splice | Splice Site (SNP) | VAF 17/99 reads (17%) | catalogued as rs1342812235, COSV57113870; called by muse, mutect2, varscan2
- TMPRSS11E | c.805T>A p.Y269N | Missense Mutation (SNP) | VAF 49/265 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59519850; called by muse, mutect2, varscan2
- TNFAIP6 | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54641505; called by muse, mutect2, varscan2
- TNFSF18 | c.270A>T p.K90N | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as COSV53440912; called by muse, mutect2, varscan2
- TNFSF4 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.091); catalogued as COSV56056911; called by muse, mutect2, varscan2
- TNR | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV54873507, COSV54891671; called by muse, mutect2, varscan2
- TOX4 | c.821G>A p.R274K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.28); catalogued as COSV52969860; called by muse, mutect2, varscan2
- TP63 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV53199759; called by muse, mutect2, varscan2
- TPX2 | c.1372C>T p.H458Y | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55917910, COSV55918947; called by muse, mutect2
- TRAF5 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs760575472, COSV54823288; called by muse, mutect2, varscan2
- TRAF7 | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV58215941; called by muse, mutect2, varscan2
- TRAV14DV4 | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs186083191; called by muse, mutect2, varscan2
- TRAV2 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.544); catalogued as rs1428178464; called by muse, varscan2
- TRBC2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.361); catalogued as rs782542057; called by muse, varscan2
- TRHDE | c.2594A>C p.D865A | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV53851363; called by muse, mutect2, varscan2
- TRIM3 | c.1576C>T p.R526* | Nonsense Mutation (SNP) | VAF 32/120 reads (27%) | catalogued as COSV61983839; called by muse, mutect2, varscan2
- TRIM46 | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100104668, COSV58115843; called by muse, mutect2
- TRIOBP | c.3083C>T p.S1028L | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs775364256, COSV60379988; called by muse, mutect2, varscan2
- TSHZ2 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.59); catalogued as rs759090660, COSV61589660; called by muse, varscan2
- TSPAN3 | c.281T>A p.F94Y | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51215238; called by muse, mutect2, varscan2
- TSSK1B | c.700A>G p.N234D | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV66815542; called by muse, mutect2, varscan2
- TTN | c.65513G>A p.R21838Q (on ENST00000591111; = p.R14414Q on NM_003319.4) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | PolyPhen possibly damaging (0.786); catalogued as rs140127488, COSV60128822, COSV60158704; called by muse, mutect2, varscan2
- TTN | c.63719G>A p.R21240Q (on ENST00000591111; = p.R13816Q on NM_003319.4) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | PolyPhen benign (0.007); catalogued as rs772700244, COSV60158740; called by muse, mutect2, varscan2
- TTN | c.50173G>A p.E16725K (on ENST00000591111; = p.E9301K on NM_003319.4) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | PolyPhen probably damaging (0.994); catalogued as COSV60158770; called by muse, mutect2, varscan2
- TTN | c.39521G>A p.G13174E (on ENST00000591111; = p.G5750E on NM_003319.4) | Missense Mutation (SNP) | VAF 29/172 reads (17%) | PolyPhen probably damaging (0.959); catalogued as rs1157011423, COSV60041104, COSV60280736; called by muse, mutect2, varscan2
- TTN | c.22990C>T p.R7664W (on ENST00000591111; = p.R6737W on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | PolyPhen possibly damaging (0.9); catalogued as rs1227497572, COSV60158883; called by muse, mutect2, varscan2
- TTN | c.16114G>A p.D5372N (on ENST00000591111; = p.D4445N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/140 reads (14%) | PolyPhen benign (0.011); catalogued as COSV100611782, COSV60158899; called by muse, mutect2, varscan2
- TUBA3C | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.518); catalogued as rs774052893, COSV68027856; called by muse, mutect2, varscan2
- TXNDC11 | c.988-2A>T p.X330_splice (on ENST00000356957 / NM_001303447.2; = p.X303_splice on NM_015914.7 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 11/44 reads (25%) | catalogued as rs760830564, COSV51600482; called by muse, mutect2, varscan2
- UGT1A3 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as COSV59384846; called by muse, mutect2, varscan2
- UGT2A3 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV52359297; called by muse, mutect2, varscan2
- UGT3A2 | c.356T>C p.L119S | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as rs747779019, COSV56931574, COSV56932792; called by mutect2, varscan2
- UNC13B | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.626); catalogued as rs372260676; called by muse, varscan2
- UNC13C | c.2728T>A p.Y910N | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.312); catalogued as COSV52891548; called by muse, mutect2, varscan2
- UNC5A | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.03); catalogued as rs763189496, COSV56168054; called by muse, mutect2, varscan2
- UNC5CL | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV55110656; called by muse, mutect2, varscan2
- UNC5D | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54807369, COSV99772027; called by muse, mutect2
- UPB1 | c.1062G>A p.W354* | Nonsense Mutation (SNP) | VAF 24/148 reads (16%) | catalogued as COSV58114335; called by muse, mutect2, varscan2
- USH2A | c.9637C>T p.P3213S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as COSV56333157, COSV99048404; called by muse, mutect2, varscan2
- USP26 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.348); catalogued as COSV63709035; called by muse, mutect2, varscan2
- USP40 | c.1268G>A p.R423K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.091); catalogued as COSV52483264, COSV99295581; called by muse, mutect2
- UTRN | c.5752G>A p.D1918N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.549); catalogued as COSV100839692; called by muse, mutect2, varscan2
- VPS13B | c.8803G>T p.E2935* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as COSV62147365, COSV62149467; called by muse, mutect2, varscan2
- VPS13C | c.7832G>A p.W2611* (on ENST00000644861 / NM_020821.3; = p.W2568* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as COSV51280302; called by muse, mutect2, varscan2
- VPS54 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1405480810, COSV55442249; called by muse, mutect2, varscan2
- VWA5A | c.510A>G p.I170M | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV63707779; called by muse, mutect2, varscan2
- WDR33 | c.2545C>T p.P849S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.081); catalogued as COSV59251520; called by muse, mutect2, varscan2
- WDR81 | c.3340A>G p.T1114A (on ENST00000409644 / NM_001163809.2; = p.T63A on NM_152348.4) | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV58484684; called by muse, mutect2, varscan2
- WNK2 | c.3994C>A p.P1332T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99941306; called by muse, mutect2, varscan2
- WNK2 | c.3995C>A p.P1332Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV99941314; called by muse, mutect2, varscan2
- WRAP73 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV99573173; called by muse, mutect2, varscan2
- XIRP2 | c.2941G>A p.E981K (on ENST00000628543; = p.E1156K on NM_152381.6) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV54712037; called by muse, mutect2, varscan2
- XYLT1 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs561119865, COSV54479080; called by muse, mutect2, varscan2
- ZBED9 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as COSV71729536; called by muse, mutect2, varscan2
- ZBTB46 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV99828874; called by muse, mutect2, varscan2
- ZFHX4 | c.3692G>A p.R1231H | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs760403982, COSV51455838; called by muse, mutect2, varscan2
- ZFPM2 | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 26/182 reads (14%) | catalogued as COSV65874458; called by muse, mutect2, varscan2
- ZG16B | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV66525984; called by muse, mutect2, varscan2
- ZNF131 | c.844T>G p.S282A (on ENST00000509156 / NM_001330707.2; = p.S248A on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.181); catalogued as COSV61003199; called by muse, mutect2, varscan2
- ZNF165 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV66102106; called by muse, mutect2, varscan2
- ZNF239 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as rs200148264; called by mutect2, varscan2
- ZNF268 | c.1024A>C p.S342R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs767710370, COSV57213416; called by muse, mutect2
- ZNF34 | c.897G>C p.R299S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV58640176; called by muse, mutect2, varscan2
- ZNF445 | c.782A>G p.D261G | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV101253696; called by muse, mutect2, varscan2
- ZNF445 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101253698; called by muse, mutect2, varscan2
- ZNF454 | c.1216C>T p.H406Y | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60768813; called by muse, mutect2, varscan2
- ZNF518B | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 26/159 reads (16%) | catalogued as COSV58723305; called by muse, varscan2
- ZNF558 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56863625; called by mutect2, varscan2
- ZNF584 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs546297340, COSV59722609; called by muse, mutect2, varscan2
- ZNF638 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV52490700; called by muse, mutect2, varscan2
- ZNF676 | c.971C>T p.S324L (on ENST00000650058; = p.S292L on NM_001001411.3) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as rs11671538, COSV68093630; called by muse, mutect2
- ZNF786 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); catalogued as COSV60276871; called by muse, mutect2, varscan2
- ZNF808 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.188); catalogued as rs1293724740, COSV63120435; called by muse, mutect2, varscan2
- ZNF831 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV64041942; called by muse, mutect2, varscan2
- ZNF831 | c.4225A>G p.T1409A | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV64041954; called by muse, mutect2, varscan2
- ZNRF4 | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as COSV55774843; called by muse, mutect2, varscan2
- ASAH2 | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- EPB41L3 | c.3072+1del p.X1024_splice | Splice Site (DEL) | VAF 41/203 reads (20%) | called by mutect2, pindel, varscan2
- NAALADL2 | c.2192A>T p.N731I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- POLR2A | c.4459C>T p.P1487S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- S100G | c.10_21del p.K4_P7del | In Frame Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 28/289 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, varscan2
- TPSG1 | c.549_557del p.S185_V187del | In Frame Del (DEL) | VAF 21/126 reads (17%) | called by mutect2, pindel, varscan2
- TRAV14DV4 | c.153T>A p.S51R | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRAV2 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, varscan2
- TRBV24-1 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TRBV30 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2
- ZNF473 | c.1635dup p.V546Cfs*18 | Frame Shift Ins (INS) | VAF 9/67 reads (13%) | called by mutect2, pindel, varscan2
- ZNF605 | c.734G>A p.R245K | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- A2M | c.471C>T p.P157= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs767862525, COSV59388736; called by mutect2, varscan2
- ABCA12 | c.4641C>T p.I1547= (on ENST00000272895 / NM_173076.3; = p.I1229= on NM_015657.3) | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as rs966377695, COSV55964847; ClinVar: likely benign; called by muse, mutect2, varscan2
- ABCA13 | c.10953C>T p.F3651= | Silent (SNP) | VAF 34/181 reads (19%) | catalogued as COSV71283655; called by muse, mutect2, varscan2
- ADAM33 | c.2106C>T p.F702= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV62935488; called by muse, mutect2
- AKR1C8P | c.201C>T p.A67= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as rs1554792896; called by muse, mutect2, varscan2
- AL645922.1 | c.1020G>A p.R340= | Silent (SNP) | VAF 76/390 reads (19%) | catalogued as COSV100190828; called by muse, mutect2, varscan2
- ALMS1 | c.7761C>T p.F2587= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs1553409598, COSV52508868; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALPK2 | c.5913C>T p.I1971= | Silent (SNP) | VAF 29/175 reads (17%) | catalogued as COSV100864886, COSV64494241; called by muse, mutect2, varscan2
- ANKRD20A4P | c.2328C>T p.F776= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as rs1347627355, COSV62003547; called by muse, mutect2, varscan2
- APBA1 | c.1368C>T p.I456= | Silent (SNP) | VAF 51/205 reads (25%) | catalogued as rs745501677, COSV55223410; called by muse, mutect2, varscan2
- APEH | c.360C>T p.F120= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV56521554, COSV99610326; called by muse, mutect2, varscan2
- APOBR | c.2349G>A p.S783= (on ENST00000431282; = p.S792= on NM_018690.4) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs758109671, COSV60489599; called by mutect2, varscan2
- ARHGAP28 | c.1413C>T p.F471= (on ENST00000383472 / NM_001366230.1; = p.F312= on NM_001010000.3) | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs374931092; called by muse, mutect2, varscan2
- ARHGAP31 | c.2751C>T p.P917= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as COSV51795372; called by muse, mutect2, varscan2
- ASTN1 | c.3549G>A p.L1183= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as rs201097215, COSV62498669, COSV62499593; called by muse, mutect2, varscan2
- ATAD5 | c.2352C>T p.S784= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV58976054; called by muse, varscan2
- ATP10B | c.3408C>T p.F1136= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV59150509, COSV59156779; called by muse, mutect2, varscan2
- ATP1A3 | c.939C>T p.S313= (on ENST00000545399 / NM_001256214.2; = p.S300= on NM_152296.5) | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV57488833; called by muse, mutect2
- ATP1B4 | c.438G>A p.T146= (on ENST00000218008 / NM_001142447.3; = p.T142= on NM_012069.5) | Silent (SNP) | VAF 58/162 reads (36%) | catalogued as rs936950156, COSV54313518; called by muse, mutect2, varscan2
- BCDIN3D | c.321C>T p.L107= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV61702590, COSV61702680; called by muse, mutect2, varscan2
- BICRA | c.1530C>T p.I510= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as rs778130367, COSV67605304; called by muse, mutect2, varscan2
- BPIFC | c.39C>T p.F13= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV55913392; called by muse, mutect2, varscan2
- BRINP1 | c.750C>T p.I250= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs865875159, COSV56297943; called by muse, mutect2, varscan2
- BTN1A1 | c.729G>A p.L243= | Silent (SNP) | VAF 40/274 reads (15%) | catalogued as COSV55068294; called by muse, mutect2, varscan2
- C11orf42 | c.294G>A p.R98= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs751313624, COSV56412490; called by muse, mutect2, varscan2
- CACNA1B | c.1215G>A p.R405= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV53133533; called by muse, mutect2, varscan2
- CAPN6 | c.813C>T p.V271= | Silent (SNP) | VAF 80/219 reads (37%) | catalogued as COSV60695682; called by muse, mutect2, varscan2
- CARMIL3 | c.3501T>C p.G1167= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV57727114; called by muse, mutect2, varscan2
- CASZ1 | c.3351C>T p.L1117= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs370369539, COSV59732378; called by muse, mutect2
- CAVIN2 | c.531C>T p.S177= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs1166956976, COSV58423425; called by muse, mutect2, varscan2
- CBWD1 | c.249G>C p.A83= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV100070696; called by mutect2, varscan2
- CCAR2 | c.1323C>T p.A441= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as rs140743871; called by muse, mutect2, varscan2
- CCDC170 | c.1998C>A p.T666= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as COSV53342582, COSV53345993; called by muse, mutect2, varscan2
- CCDC42 | c.39G>A p.E13= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV53449135; called by muse, mutect2, varscan2
- CCT8L2 | c.360G>A p.E120= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV63462959; called by muse, mutect2, varscan2
- CD55 | c.561C>T p.S187= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV58577343; called by muse, mutect2, varscan2
- CDC20 | c.417T>C p.N139= | Silent (SNP) | VAF 21/134 reads (16%) | catalogued as rs1276776528, COSV60522370; called by muse, mutect2, varscan2
- CDH23 | c.2499C>T p.I833= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as COSV54940802; called by muse, mutect2, varscan2
- CDK18 | c.507G>A p.G169= (on ENST00000506784 / NM_212503.3; = p.G139= on NM_002596.4) | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV63728067; called by muse, mutect2, varscan2
- CELSR2 | c.8463G>A p.E2821= | Silent (SNP) | VAF 46/277 reads (17%) | catalogued as COSV54774637; called by muse, mutect2, varscan2
- CERS6 | c.13T>C p.L5= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV59831848; called by muse, mutect2, varscan2
- CFAP43 | c.2173C>T p.L725= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV53378649, COSV53379062; called by muse, mutect2, varscan2
- CHGB | c.912G>A p.K304= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV66760903; called by muse, mutect2, varscan2
- CLDN1 | c.372G>A p.A124= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as rs545795665, COSV55043622; called by muse, mutect2, varscan2
- CNTNAP2 | c.2175C>T p.I725= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV62208509; called by muse, mutect2, varscan2
- COL4A5 | c.1875C>T p.F625= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as rs1239337307, COSV60364795; called by muse, mutect2, varscan2
- CRB1 | c.1776C>T p.I592= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs753491387, COSV66331089, COSV66331219; called by muse, mutect2, varscan2
- CSMD1 | c.5535G>A p.V1845= (on ENST00000520002; = p.V1844= on NM_033225.6) | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV59342854; called by muse, mutect2, varscan2
- CSMD1 | c.5421C>T p.F1807= (on ENST00000520002; = p.F1806= on NM_033225.6) | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV59309178; called by muse, mutect2, varscan2
- CSMD1 | c.2040C>T p.S680= (on ENST00000520002; = p.S679= on NM_033225.6) | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV59342892; called by mutect2, varscan2
- CSMD3 | c.5583G>A p.K1861= (on ENST00000297405 / NM_001363185.1; = p.K1757= on NM_052900.3) | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV52225606; called by muse, mutect2, varscan2
- CTIF | c.321C>T p.S107= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV56486543; called by muse, mutect2, varscan2
- CUL9 | c.2625C>T p.N875= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as rs763439384, COSV52730557; called by muse, mutect2, varscan2
- CXCR2 | c.876C>T p.I292= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as rs199873547, COSV59281178; called by muse, mutect2, varscan2
- CYP2C18 | c.411G>A p.G137= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs1046402688, COSV53669874; called by muse, mutect2, varscan2
- CYP2C19 | c.1183C>T p.L395= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as COSV64908303; called by muse, mutect2, varscan2
- CYP4B1 | c.1485G>A p.K495= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as COSV54724384; called by muse, mutect2, varscan2
- DHX16 | c.1014C>T p.S338= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV64564563; called by muse, mutect2
- DHX57 | c.336A>G p.K112= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as COSV54887140; called by muse, mutect2, varscan2
- DNAH5 | c.3066C>T p.V1022= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV54235466; called by muse, mutect2, varscan2
- DNM3 | c.891G>A p.R297= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs769846099, COSV62455271, COSV62461375; called by muse, mutect2, varscan2
- DOCK8 | c.5397C>T p.F1799= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV101210075; called by muse, mutect2, varscan2
- DOP1B | c.1857G>A p.K619= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as rs1040038534, COSV101215136; called by muse, mutect2, varscan2
- DOP1B | c.5451C>T p.P1817= | Silent (SNP) | VAF 31/177 reads (18%) | catalogued as rs533466502, COSV67693982; called by muse, mutect2, varscan2
- DSC3 | c.174C>T p.F58= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV64572690, COSV64573749; called by muse, mutect2, varscan2
- DUOX2 | c.2089C>T p.L697= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs371950111; called by muse, mutect2, varscan2
- DYSF | c.4401C>T p.I1467= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV50372292; called by muse, mutect2, varscan2
- DZIP3 | c.1662C>A p.P554= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV64312641; called by muse, mutect2, varscan2
- EDC4 | c.2169C>T p.S723= | Silent (SNP) | VAF 39/211 reads (18%) | catalogued as COSV59303107; called by muse, mutect2, varscan2
- ENTHD1 | c.1641C>T p.S547= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV57321919, COSV57324462; called by muse, mutect2, varscan2
- EXOC4 | c.1131C>T p.I377= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as rs1170941256, COSV54105675; called by muse, mutect2
- F13A1 | c.876C>T p.A292= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV53561354; called by muse, varscan2
- FAM131A | c.903C>T p.C301= (on ENST00000310585; = p.C332= on NM_144635.5) | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99658310; called by muse, mutect2, varscan2
- FAP | c.1752C>T p.L584= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV51863832; called by muse, mutect2, varscan2
- FCGBP | c.11517G>A p.E3839= | Silent (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- FGD5 | c.1293G>A p.V431= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV53246213; called by muse, mutect2, varscan2
- FGFR1 | c.930C>T p.I310= (on ENST00000447712 / NM_023110.3; = p.I308= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV58337902; called by muse, mutect2, varscan2
- FNBP4 | c.441C>T p.N147= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV55449881; called by muse, mutect2, varscan2
- FRAS1 | c.10479C>T p.S3493= | Silent (SNP) | VAF 44/241 reads (18%) | catalogued as COSV53623142; called by muse, mutect2, varscan2
- FRMPD3 | c.4581C>T p.I1527= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV52193014; called by muse, mutect2, varscan2
- FSHR | c.378A>G p.L126= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV58627131; called by muse, mutect2, varscan2
- FUT9 | c.159C>T p.F53= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV56146508, COSV56150205; called by muse, mutect2, varscan2
- FYB2 | c.549G>A p.R183= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV58585359; called by muse, mutect2, varscan2
- GABRD | c.72G>A p.A24= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs772327427, COSV66079963; ClinVar: likely benign; called by muse, mutect2
- GABRE | c.771C>T p.I257= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs868233464, COSV64820155; called by muse, mutect2
- GARRE1 | c.114C>T p.G38= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100209131; called by muse, mutect2, varscan2
- GGCX | c.87G>A p.R29= | Silent (SNP) | VAF 17/279 reads (6%) | catalogued as COSV52089057; called by muse, mutect2
- GIMAP1 | c.429C>T p.V143= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV56188809; called by muse, mutect2, varscan2
- GLRA4 | c.807C>T p.I269= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as rs760796613, COSV65455304, COSV65456626; called by muse, mutect2, varscan2
- GLT6D1 | c.156C>T p.L52= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs755779235, COSV65627750; called by muse, mutect2, varscan2
- GPR179 | c.5496G>A p.L1832= (on ENST00000621958; = p.L1831= on NM_001004334.4) | Silent (SNP) | VAF 21/135 reads (16%) | called by muse, mutect2, varscan2
- GRID2 | c.1761G>A p.L587= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as COSV56224457, COSV99940798; called by muse, mutect2, varscan2
- GRM7 | c.840C>T p.S280= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV63150923; called by muse, mutect2, varscan2
- GTF3C2 | c.2430C>T p.L810= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs764913410, COSV51990982; called by muse, mutect2, varscan2
- HECTD4 | c.2782C>T p.L928= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV61180166; called by muse, mutect2, varscan2
- HMGCS2 | c.1155C>T p.S385= | Silent (SNP) | VAF 93/579 reads (16%) | catalogued as COSV65568371; called by muse, mutect2, varscan2
- HOMER3 | c.819C>G p.T273= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV55356890; called by muse, mutect2, varscan2
- HSH2D | c.723G>A p.V241= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV53738579; called by muse, mutect2, varscan2
- IL1R2 | c.96G>A p.G32= | Silent (SNP) | VAF 26/157 reads (17%) | catalogued as COSV60208155; called by muse, mutect2, varscan2
- IL1RL1 | c.1566C>T p.S522= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs1346407021, COSV52117880; called by mutect2, varscan2
- IL36B | c.357C>T p.F119= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV52087141, COSV52088296; called by muse, mutect2, varscan2
- IL37 | c.213C>T p.V71= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV54491693; called by muse, mutect2, varscan2
- INPPL1 | c.3192C>T p.F1064= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV53356847; called by muse, mutect2, varscan2
- IQSEC3 | c.2730G>A p.K910= (on ENST00000538872 / NM_001170738.2; = p.K607= on NM_015232.1) | Silent (SNP) | VAF 41/196 reads (21%) | catalogued as rs144152224; called by muse, mutect2, varscan2
- ISX | c.354G>A p.R118= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs764179371, COSV58087333; called by muse, mutect2
- ITGB8 | c.618G>A p.R206= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV56006224; called by muse, mutect2, varscan2
- ITK | c.700C>T p.L234= | Silent (SNP) | VAF 69/366 reads (19%) | catalogued as COSV70063365; called by muse, mutect2, varscan2
- KATNB1 | c.261C>T p.I87= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV101109975, COSV65560793; called by muse, mutect2, varscan2
- KAZALD1 | c.636C>T p.I212= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100930571; called by muse, mutect2, varscan2
- KCNJ6 | c.684G>A p.R228= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV55712899; called by muse, mutect2, varscan2
- KCNU1 | c.3093T>C p.D1031= | Silent (SNP) | VAF 25/134 reads (19%) | catalogued as COSV67757437; called by muse, mutect2, varscan2
- KIAA0319L | c.1317C>T p.I439= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs749946295, COSV57845918; called by muse, mutect2, varscan2
- KIAA0586 | c.3528C>T p.F1176= (on ENST00000619416 / NM_001244190.2; = p.F1115= on NM_014749.5) | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV54177971; called by muse, mutect2, varscan2
- KPNA1 | c.1041G>A p.L347= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs372699562; called by muse, mutect2, varscan2
- KRTAP27-1 | c.453C>T p.F151= | Silent (SNP) | VAF 41/200 reads (21%) | catalogued as rs781274963, COSV67000922; called by muse, mutect2, varscan2
- KRTAP5-3 | c.69C>T p.G23= | Silent (SNP) | VAF 31/152 reads (20%) | catalogued as COSV68790867; called by muse, mutect2, varscan2
- LPAR4 | c.978C>T p.A326= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV70912914; called by muse, mutect2, varscan2
- LRP1 | c.4104C>T p.I1368= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs1241463168, COSV54516485; called by muse, mutect2, varscan2
- LRP1B | c.522A>T p.G174= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV67241526; called by muse, mutect2, varscan2
- LRRC7 | c.165C>T p.F55= (on ENST00000651989 / NM_001370785.2; = p.F22= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs1042784977, COSV50495873; called by muse, mutect2, varscan2
- LTA | c.564C>T p.I188= | Silent (SNP) | VAF 37/163 reads (23%) | catalogued as COSV69304952; called by muse, mutect2, varscan2
- LY6G6C | c.336C>T p.F112= | Silent (SNP) | VAF 110/589 reads (19%) | catalogued as COSV65404706; called by muse, mutect2, varscan2
- MACF1 | c.12183C>T p.L4061= (on ENST00000372915; = p.L1994= on NM_012090.5) | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV57129051; called by muse, mutect2, varscan2
- MAGEA4 | c.732G>A p.R244= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs1169568726, COSV52342057; called by muse, mutect2, varscan2
- MAK16 | c.9G>A p.S3= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as rs147879677, COSV64078405; called by muse, mutect2, varscan2
- MALT1 | c.1161T>G p.T387= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV61935447; called by muse, mutect2, varscan2
- MAML2 | c.3003A>G p.Q1001= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV73263917; called by muse, mutect2, varscan2
- MAN1C1 | c.969C>T p.I323= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV99847941, COSV99847991; called by muse, mutect2, varscan2
- MAP1A | c.3426C>T p.D1142= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV55810262; called by mutect2, varscan2
- MDN1 | c.7492C>T p.L2498= | Silent (SNP) | VAF 36/154 reads (23%) | catalogued as COSV65524162; called by muse, mutect2, varscan2
- MEP1B | c.1305G>A p.R435= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV52498364; called by muse, mutect2, varscan2
- MGAM | c.3738C>T p.F1246= | Silent (SNP) | VAF 66/365 reads (18%) | catalogued as COSV72074971; called by muse, mutect2, varscan2
- MGAT2 | c.1071T>C p.C357= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV53566538; called by muse, mutect2, varscan2
- MGAT5 | c.2169C>T p.V723= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV56096961; called by muse, mutect2
- MLKL | c.51G>A p.R17= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs1281837305, COSV58204183; called by muse, mutect2, varscan2
- MMP17 | c.300C>T p.A100= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs772506679, COSV62180135; called by muse, mutect2, varscan2
- MMP25 | c.123C>T p.Y41= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV100339365; called by muse, mutect2, varscan2
- MTHFR | c.1222C>T p.L408= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV57173139; called by muse, mutect2, varscan2
- MUC16 | c.21567C>T p.P7189= | Silent (SNP) | VAF 30/147 reads (20%) | catalogued as COSV67476158; called by muse, mutect2, varscan2
- MUC16 | c.9126C>T p.F3042= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV67459530; called by muse, mutect2, varscan2
- MUC17 | c.9060T>G p.T3020= | Silent (SNP) | VAF 68/316 reads (22%) | catalogued as COSV60293521; called by muse, mutect2, varscan2
- MUC21 | c.1131C>T p.N377= | Silent (SNP) | VAF 18/146 reads (12%) | catalogued as COSV66221377; called by muse, mutect2, varscan2
- MXRA5 | c.8415C>T p.A2805= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1290233773, COSV54240258; called by muse, mutect2, varscan2
- MYH9 | c.1056C>T p.I352= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs727504861, COSV53388758; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO16 | c.5466T>C p.A1822= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV62753280; called by muse, mutect2, varscan2
- MYO5B | c.540C>T p.F180= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as rs370497980; called by muse, mutect2, varscan2
- MYOCD | c.297G>A p.L99= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as COSV58506429; called by muse, mutect2, varscan2
- MYOF | c.4134C>T p.I1378= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV63700059; called by muse, mutect2, varscan2
- NBAS | c.4770C>T p.F1590= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as COSV55727335; called by muse, mutect2, varscan2
- NCKAP1L | c.2832G>A p.K944= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV53208702; called by muse, mutect2, varscan2
- NCKAP5 | c.4992A>G p.G1664= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV58454745; called by muse, mutect2, varscan2
- NECTIN4 | c.1191C>T p.S397= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV63513168, COSV63514281; called by muse, mutect2, varscan2
- NEUROD4 | c.696G>A p.L232= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs769231012, COSV54472414; called by muse, mutect2, varscan2
162 further variants in this file (0 protein-altering or splice-affecting, 135 silent, 27 other) are not listed here.
